Surgical pathology report (de-identified scan), TCGA case TCGA-23-2641, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Cedars Sinai, specimen TCGA-23-2641-01A (Primary Tumor).

[page 1 of 10]
SURGICAL PATHOLOGY REPORT

***** Addendum - Please See End of Report *****
Reason for Addendum #1: Additional sections or studies

DIAGNOSIS:

SYNOPTIC REPORT:

APPLIES TO:

- A : DIAPHRAGM TUMOR
- B : TRANSVERSE COLON TUMOR
- C : OMENTUM
- D : PERINEPLIRIC TUMOR
- E : SMALL BOWEL TUMOR
- F : RECTO SIGMOID TUMOR
- G : PELVIC TUMOR
- H : RT TUBE & OVARY LT TUBE & OVARY UTERUS
- I : RIGHT PELVIC TUMOR
- J : LEFT PERI URETERAL TUMOR
- K : LEFT PELVIC LYMPH NODES
- M : APPENDIX
- N : GASTRIC OMENTUM

SPECIMEN TYPE:

MACROSCOPIC

OTHER ORGANS PRESENT:

PROCEDURE:

SPECIMEN INTEGRITY:

SPECIMEN INTEGRITY LEFT OVARY:

LEFT AND RIGHT OVARIES
LEFT AND RIGHT FALLOPIAN TUBES
UTERUS
DIAPHRAGM, TRANSVERSE COLON, OMENTUM,
PERINEPHRIC TISSUE, SMALL INTESTINE,
RECTOSIGMOID COLON, PELVIC TISSUE, LEFT
PERIURETERAL TISSUE, LEFT PELVIC LYMPH
NODES, RIGHT AORTIC LYMPH NODES,
APPENDIX, GASTRIC OMENTUM
RIGHT SALPINGO-OOPHORECTOMY
LEFT SALPINGO-OOPHORECTOMY
HYSTERECTOMY
OMENTECTOMY
PERITONEAL BIOPSIES
APPENDECTOMY; BIOPSIES OF MULTIPLE SITES
INTACT
INTACT

[page 2 of 10]
[REDACTED] [REDACTED]

.....OSCOPIC

HISTOLOGIC TYPE:	SEROUS ADENOCARCINOMA
HISTOLOGIC GRADE:	G3: POORLY DIFFERENTIATED
TUMOR SIZE:	CANNOT BE DETERMINED (SEE COMMENT)
OVARIAN SURFACE INVOLVEMENT:	PRESENT
IMPLANTS:	NOT APPLICABLE/NON SAMPLED
SUMMARY OF ORGANS/TISSUES MICROSCOPICALLY INVOLVED BY TUMOR:	ONE OVARY FALLOPIAN TUBE(S) OMENTUM PERITONEUM BILATERAL ADNEXAL LIGAMENTS, PARAMETRIAL SOFT TISSUES, DIAPHRAGM, PERICOLIC/PERIRECTAL TISSUES, SMALL INTESTINE, PERINEPHRIC AREA, PERIURETERAL AREA, LEFT PELVIC LYMPH NODE, GASTRIC OMENTUM
LYMPHOVASCULAR INVASION:	PRESENT

PRIMARY TUMOR (PT):	PT3C : MACROSCOPIC PERITONEAL METASTASIS BEYOND PELVIS MORE THAN 2 CM IN GREATEST DIMENSION AND/OR REGIONAL LYMPH NODE METASTASIS
REGIONAL LYMPH NODES (PN):	PN1: REGIONAL LYMPH NODE METASTASIS
NUMBER OF LYMPH NODES IDENTIFIED:	7
NUMBER OF LYMPH NODES INVOLVED:	1

ADDITIONAL PATHOLOGIC FINDINGS

SEE BODY OF DIAGNOSTIC SECTION OF THE REPORT.

COMMENT(S)

THE TUMOR IS CONSIDERED TO REPRESENT A PRIMARY PERITONEAL NEOPLASM.

- A. SOFT TISSUE, DIAPHRAGM, "TUMOR", EXCISION:
- Mullerian-derived carcinoma with high-grade serous features (see comment)
- B. COLON, TRANSVERSE, "TUMOR", EXCISION:
- Mullerian-derived carcinoma with high-grade serous features (see comment)
- No large intestinal tissue identified
- C. OMENTUM, PARTIAL OMENTECTOMY:
- Extensive involvement (subtotal replacement) by mullerian-derived carcinoma with high-grade serous features (see comment)
- D. [SOFT TISSUE], PERINEPHRIC, "TUMOR", EXCISION:
- Mullerian-derived carcinoma with high-grade serous features (see comment)
- E. SMALL INTESTINE, DESIGNATED "SMALL BOWEL TUMOR", EXCISION:
- Mullerian-derived carcinoma with high-grade serous features (see comment)

SURGICAL PATHOLOGY REPORT

[page 3 of 10]
F. [SOFT TISSUE AND LYMPHOID TISSUE], SPECIMEN DESIGNATED "RECTOSIGMOID TUMOR", EXCISION:

- Mullerian-derived carcinoma with high-grade serous features (see comment)
- No large intestinal tissue identified

G. SOFT TISSUE, DESIGNATED "PELVIC TUMOR", EXCISION:

- Mullerian-derived carcinoma with high-grade serous features (see comment)

H. UTERUS, FALLOPIAN TUBES, AND OVARIES, TOTAL ABDOMINAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY:

- High-grade serous carcinoma involving:
- Serosal surface of smaller ovary (laterality uncertain) and focally invading cortex of smaller ovary; latter tumor deposits measure up to 0.5 cm in diameter
- Serosal surfaces of both fallopian tubes
- Paraovarian and paratubal adnexal soft tissues/ligaments, bilaterally
- No evidence of carcinoma involving cervix or vaginal cuff
- Other findings:
- Smaller ovary also shows atrophic changes, cystic epithelial inclusions, a small (about 1.0 cm diameter) benign serous cystadenofibroma and serosal adhesions
- Larger ovary (laterality uncertain) shows near total replacement by a benign serous cystadenofibroma, cystic epithelial inclusions, and atrophic changes
- Incidental (less than 0.3 cm diameter) benign serous adenofibroma, paratubal (laterality uncertain) in adnexa ipsilateral to smaller ovary
- Both fallopian tubes also show age-related changes
- Bilateral paratubal Walthard rests, mostly cystic and focally solid
- Cervix with extensive ulceration, associated necrosis, acute and chronic inflammation, fibrosis, hyperplasia of squamous epithelium adjacent to ulcer, secondary reactive epithelial changes, parakeratosis, squamous metaplasia, and nabothian cysts
- Vaginal cuff mucosa with chronic and mild acute inflammation, mild squamous hyperplasia, and parakeratosis
- Inactive/atrophic endometrium with some cystically dilated glands
- Adenomyosis
- Adhesions involving uterine serosa and adnexal structures

J. [SOFT TISSUE] LEFT PERIURETERAL REGION, "TUMOR", EXCISION:

- Positive for mullerian-derived carcinoma with high-grade serous features (see comment)

K. LYMPH NODES, LEFT PELVIC, EXCISION:

- One of three lymph nodes is positive for metastatic serous carcinoma; metastatic tumor is present in an afferent lymphatic and focally in the subcapsular sinus of the affected lymph node (see comment)

L. LYMPH NODES, RIGHT AORTIC, EXCISION:

- Three reactive lymph nodes
- No evidence of metastatic carcinoma (0/3)

M. VERMIFORM APPENDIX, APPENDECTOMY:

[page 5 of 10]
-
- Mullerian-derived carcinoma with high-grade serous features involving partially coating surface of (mesoappendix)
- Partial obliteration of lumen of appendix by fibrous tissue in mid portion and tip

N. OMENTUM, GASTRIC, PARTIAL OMENTECTOMY:

- Mullerian-derived carcinoma with high-grade serous features extensively involving omental adipose tissue
- One small omental lymph node is negative for metastatic carcinoma (0/1)

COMMENT: The high-grade serous carcinoma extensively involves omentum and coats peritoneal surfaces, in addition to involving the serosal surface and focally invading an atrophic ovary. The tumor appears to represent a primary peritoneal carcinoma. Lymphovascular invasion by carcinoma is present in most of the involved site. Tumor-associated necrosis, secondary acute and chronic inflammatory changes, fibrosis, and adhesions are also noted in the vicinity of tumor. T

HISTORY:
Ovarian cancer

MICROSCOPIC FINDINGS:
See diagnosis.

SPECIAL STUDIES:
H&E-stained short step sections (F1 x1, H7 x1, M1 x1, N1 x1)

IMMUNOHISTOCHEMISTRY:
None

GROSS:
A. DIAPHRAGM TUMOR
Labeled with the patient's name, labeled "diaphragm tumor", and received in formalin is a 6.0 x 4.0 x 1.5 cm aggregate of multiple soft to semisoft tan-yellow tissue fragments. The individual fragments range from about 0.2 to 3.0 cm in maximum dimension.

The tissue fragments appear to consist mostly of tumor. Tumor-associated necrosis and focal hemorrhage are also noted.

Representative sections are submitted.

Slide key:
A1-A3. Multiple

B. TRANSVERSE COLON TUMOR
Labeled with the patient's name, labeled "transverse colon tumor", and received in formalin are two fragments of firm tan tissue, about 1.0 x 0.5 x 0.2 cm and 0.6 x 0.4 x 0.2 cm. Each of the tissue fragments appears to consist of tumor.

No colonic tissue is evident on gross inspection of the specimen.

Entirely submitted.

[page 6 of 10]
Slide key:
B1. 2

C. OMENTUM

Labeled with the patient's name, labeled "omentum", and received in formalin is a 35.0 x 10.0 x 2.0 cm partial omentectomy specimen.

The omentum shows extensive involvement by tumor. There are nodular plaque-like tumor which involve about 90% of the total volume of the omentum.

Representative sections are submitted.

Slide key:
C1. 1

D. PERINEPHRIC TUMOR

Labeled with the patient's name, labeled "perinephric tumor", and received in formalin is a 4.0 x 3.5 x 1.2 cm aggregate of multiple fragments of semi-firm to firm tan tissue. The individual tissue fragments range from about 0.2 to 2.0 cm in maximum dimension. The tissue fragments appear to be virtually replaced by tumor.

Representative sections submitted.

Slide key:
D1. Multiple

E. SMALL BOWEL TUMOR

Labeled with the patient's name, labeled "small bowel tumor", and received in formalin is a 1.0 x 0.6 x 0.2 cm aggregate of several tiny to small fragments of semi-soft to firm tan tissue.

The tissue fragments appear to each consist of tumor.

Entirely submitted.

Slide key:
E1. Multiple

F. RECTOSIGMOID TUMOR

Labeled with the patient's name, labeled "rectosigmoid tumor", and received in formalin are multiple fragments of firm tan tissue ranging from 0.2 to 1.0 cm in maximum dimension and amounting in aggregate to 1.5 x 1.4 x 0.5 cm.

All the tissue fragments appear to be replaced by tumor.

Entirely submitted.

Slide key:
F1. Multiple

G. PELVIC TUMOR

Labeled with the patient's name, labeled "pelvic tumor", and received in formalin are multiple fragments of firm tan tissue ranging from about 0.1 to 0.7 cm in maximum dimension and amounting in aggregate to 1.5 x 1.0 x 0.8 cm.

[page 7 of 10]
[REDACTED]

The tissue fragments each appear to be replaced by tumor. Focal hemorrhages are also noted.

Entirely submitted.

Slide key:

G1. Multiple

H. RIGHT TUBE AND OVARY, LEFT TUBE AND OVARY, UTERUS

Labeled with the patient's name, labeled "right tube and ovary, left tube and ovary, and uterus", received fresh in the Operating Room and subsequently fixed in formalin is a 116 gram total hysterectomy and bilateral salpingo-oophorectomy specimen. The adnexa are separate from the uterus. No instructions for orientation are provided. The uterus is about 6.2 x 4.5 x 4.0 cm in greatest overall dimensions. The cervical portion of the uterus is about 2.0 cm long and up to 3.5 cm in diameter. The endometrial cavity is about 3.0 cm long and up to 1.5 cm in width. The endometrial mucosa has a maximum thickness of 0.1 cm. The muscular uterine wall has a maximum thickness of about 1.5 cm. Attached to the cervix there is a cuff of vaginal tissue lined by tan mucosa that is up to 2.0 cm in length posteriorly, and up to 0.5 cm in length, anteriorly. The laterality of the adnexal structures is uncertain. The larger of the two ovaries is 4.5 x 2.5 x 2.4 cm. The ipsilateral fallopian tube has fimbria at one end, is about 5.0 cm in length and up to 0.5 cm in diameter. The adjacent adnexal soft tissues measure up to about 3.0 cm in width. The smaller ovary is about 2.0 x 1.5 x 1.2 cm. The second fimbriated fallopian tube is 4.5 cm long and ranges from about 0.3 to 0.6 cm in diameter.

There are multiple semi-soft to firm tan tumor nodules involving the serosal surface of the smaller ovary and focally invading the cortex of the smaller ovary. These tumor deposits measure up to 0.5 cm in diameter. There are also plaque-like and nodular aggregates of semi-soft to firm tan tumor involving the adnexal soft tissues, bilaterally and the serosal surfaces of both fallopian tubes. There are friable tan tumor deposits amounting in aggregate to about 1.5 x 1.0 x 0.5 cm involving the parauterine soft tissues. No gross tumor is seen in the uterus, including the cervical portion of the uterus, or vaginal cuff.

The larger ovary appears to be subtotally replaced by a mostly cystic and focally solid tumor that is about 4.5 cm in maximum dimension. The cystic neoplasm in the larger ovary is multiloculated and contains yellow fluid. The linings are tan-white and smooth, for the most part. There is some tan-white fibrous tissue in the cyst wall. The smaller ovary also shows multiple tiny to small cysts, ranging from less than 0.1 to about 0.8 cm in diameter. There appears to be some concentration of cysts with some intervening white fibrous tissue over an area measuring about 1.0 cm in diameter in the smaller ovary. Adhesions involving the adnexal structures and focally involving the serosa of the uterus are also noted. No gross pathologic lesions of the endometrium or myometrium are seen. The cervix shows extensive mucosal ulceration with focal associated necrosis. No gross pathologic lesions of the vaginal cuff are seen.

Ink key: Vaginal cuff margin - blue.

Representative sections submitted.

Slide key:

H1, H2. Posterior vaginal cuff - 2 each

H3. Anterior cervix 12:00-3:00 - 1

H4. Anterior cervix 9:00-12:00 - 1

H5. Posterior cervix 3:00-6:00 - 1

H6. Posterior cervix 6:00-9:00 - 1

H7. Anterior uterus - 1

H8. Posterior uterus - 1

H9, H10. Portions of smaller ovary - 2, 3

H11. Portions of fallopian tube of the smaller ovary - 4

H12, H13. Portions of the larger ovary - 3 each

SURGICAL PATHOLOGY REPORT

[page 8 of 10]
H14. Portions of fallopian tube of the larger ovary - 3
H15, H16. Additional sections of the larger ovary - 2 each
H17. Additional section of larger ovary and tumor involving paraovarian tissue - 2
H18, H19. Additional sections of uterus and parauterine tissues - 2 each

I. RIGHT PELVIC TUMOR

Labeled with the patient's name, labeled "right pelvic tumor", and received in formalin is about a 5.0 x 3.0 x 0.5 cm portion of tan and yellow soft tissue.

The soft tissues are coated by nodular and plaque-like aggregates of semi-soft to firm tan tumor which involves about 90% of the surface are one aspect of the tissue fragments.

Representative sections are submitted.

Slide key:

I1. Multiple

J. LEFT PERIURETERAL TUMOR

Labeled with the patient's name, labeled "left periureteral tumor", and received in formalin is about a 2.0 x 1.5 x 0.5 cm aggregate of multiple fragments of semi-soft to firm tan tissue and blood clot.

The tissue fragments appear to consist mostly of tumor.

Entirely submitted.

Slide key:

J1. Multiple

K. LEFT PELVIC LYMPH NODE

Labeled with the patient's name, labeled "left pelvic lymph node", and received in formalin are two aggregates of yellow adipose tissue and lymph nodes, about 3.0 x 1.5 x 0.8 cm and 1.4 x 0.6 x 0.3 cm. Dissection reveals three semi-firm tan lymph nodes, about 0.3, 0.5, and 2.5 cm in maximum dimension.

No metastatic tumor is evident on gross inspection of the specimen.

The lymph nodes are each entirely embedded along with some of the perinodal fat.

Slide key:

K1. Half of second largest lymph node and one smaller lymph node - 2

K2. Other half of largest lymph node and second half of second largest lymph node - 2

L. RIGHT AORTIC LYMPH NODE

Labeled with the patient's name, labeled "right aortic lymph node", and received in formalin are two aggregates of yellow adipose tissue and lymph nodes, about 2.2 x 1.2 x 0.7 cm and 1.5 x 1.0 x 0.4 cm. There are a total of three semi-firm tan lymph nodes, about 0.3, 0.7, and 1.5 cm in maximum dimensions.

No metastatic tumor is evident on gross inspection of the specimen.

The entire specimen is submitted.

Slide key:

L1. Largest lymph node, sectioned into three pieces - 3

L2. Two smaller lymph nodes - 1

[page 9 of 10]
[REDACTED]

M. APPENDIX

Labeled with the patient's name, labeled "appendix", and received in formalin is a 4.0 cm long, up to 0.6 cm diameter vermiform appendix. There is attached fatty mesoappendix that measures up to 2.5 cm in width.

The mesoappendix is partially coated by plaque-like and nodular aggregates of firm tan tumor, measuring up to about 1.4 cm in maximum dimensions.

The appendix shows luminal obliteration by fibrous tissue in the mid and distal portions. No fecaliths, exudates or perforations of the appendix are evident.

Representative sections are submitted.

Slide key:

M1. Distal, mid and proximal segments of appendix and mesoappendix with tumor - 3

N. GASTRIC OMENTUM

Labeled with the patient's name, labeled "gastric omentum", and received in formalin is an 8.5 x 4.5 x 2.5 cm partial omentectomy specimen.

The omentum is subtotally replaced by nodular and plaque-like aggregates of firm tan tumor amounting in aggregate to about 4.0 x 2.5 x 2.0 cm.

Representative sections are submitted.

Slide key:

N1. 1

[REDACTED]

**INTRAOPERATIVE CONSULTATION:
OPERATIVE CALL**

[SPECIMEN] H:

- A 0.5 cm portion of villous-appearing tumor submitted to [REDACTED] for research.
- Opposite ovary opened to reveal a polycystic interior filled with about 5 cc of yellow mucinous
- [REDACTED]
- [REDACTED]

This addendum is issued to report the results of examination of tissue for TCGA studies. Tissue was submitted for TCGA during intraoperative consultation

O. TCGA A, RESEARCH:

- Mullerian type adenocarcinoma, high grade, with serous features:
- 99% tumor cell nuclei
- Tumor cell necrosis: Not identified

SURGICAL PATHOLOGY REPORT

[page 10 of 10]
P. TCGA B, RESEARCH:

- Mullerian type adenocarcinoma, high grade, with serous features:
- 99% tumor cell nuclei
- Tumor cell necrosis: Not identified

Q. TCGA C, RESEARCH:

- Mullerian type adenocarcinoma, high grade, with serous features:
- 99% tumor cell nuclei
- Tumor cell necrosis: Not identified

R. TCGA C, RESEARCH:

- Mullerian type adenocarcinoma, high grade, with serous features:
- 995% tumor cell nuclei
- Tumor cell necrosis: Not identified
-

Source: NCI Genomic Data Commons file 1a380c5c-e6b6-4c55-a2db-b99a465c3a6f (TCGA-23-2641.0B8F79BA-DBF1-4978-9661-BB0B0DCC8768.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).